Gene-level copy-number profile of tumor specimen TCGA-DD-AAEK-01A from TCGA case TCGA-DD-AAEK, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 51.4 years (18,757 days).
Specimen TCGA-DD-AAEK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.cc021ec9-47ee-494a-ab94-b38c7f5f2e91.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AAEK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b0684acc-e339-4c94-9226-dbf4d8c5f49b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,399; copy number 2: 13,967; copy number 3: 22,498; copy number 4: 19,204; copy number 5: 420; copy number 6: 1,189; copy number 7: 84; copy number 8: 28; copy number 9: 8; copy number 10: 11; copy number 14: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AAEK-01A-11D-A40Q-01): tumor purity 0.44, ploidy 3.18, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 138 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–4,970,425, 103 genes, copy number 7–14 (broad region; genes not listed).
- chr5:5,375,723–5,694,742, 7 genes, copy number 7: ALG3P1, AC091978.1, MTCO1P30, MTCO2P30, MTCO1P31, ICE1, AC026736.1.
- chr5:6,289,857–7,364,531, 28 genes, copy number 8: HMGB3P3, LINC02145, MED10, AC093307.1, UBE2QL1, AC027334.1, LINC01018, NSUN2, SRD5A1, LINC02102, TENT4A, LINC02236, AC122710.2, MIR4278, LINC02196, RN7SKP79, AC122710.1, RNA5SP176, AC025756.1, AC091889.1, Metazoa_SRP, AC091951.4, AC091951.2, AC091951.3, AC091951.1, AC027343.3, LINC02123, AC027343.1.

Autosomal genes at a single copy (total copy number 1): 12. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
